MMRF case MMRF_2082 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c6c21cbd-97db-4cca-8715-1271101062b7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.4 years (24,620 days); ISS stage: I; Days to last known disease status: 742 days (2.0 years); Days to last follow up: 742 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 284 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 437 days (1.2 years); Days to treatment end: 498 days (1.4 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 508 days (1.4 years); Days to treatment end: 508 days (1.4 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 510 days (1.4 years); Days to treatment end: 510 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 742.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 1): M Protein 2.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 137 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 20.8 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 3.09 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 48 g/L; Total Protein 8.8 g/dL; Glucose 5.28 mmol/L.
- Day 57 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Leukocytes 9.59 ×10⁹/L; Absolute Neutrophil 5.56 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.
- Day 113 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.59 ×10⁹/L; Platelets 313 ×10⁹/L.
- Day 197 (ECOG 0): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.88 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 4.4 mmol/L.
- Day 302 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 1.23 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.55 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 413 (ECOG 0): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 1.16 g/L; Beta 2 Microglobulin 2.31 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 8.1 g/dL; Glucose 4.62 mmol/L.
- Day 526 (ECOG 0): M Protein 0.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.552 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.6 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.93 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 575 (ECOG 0): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.853 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 4.84 mmol/L.
- Day 699: M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -27: Weight: 61 kg; Height: 168 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_2082_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_2082_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
